Somatic mutation profile of tumor specimen TCGA-13-1412-01A (aliquot TCGA-13-1412-01A-01W-0494-09) from TCGA case TCGA-13-1412, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 41.4 years (15,119 days).
Specimen TCGA-13-1412-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41b30d2a-2b21-49c9-bcd2-eb4d79e46b46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1412-10A (Blood Derived Normal), aliquot TCGA-13-1412-10A-01W-0493-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/539100fb-7a5c-4c76-8a80-3148cd66d2b3

The open-access MAF lists 42 somatic variants for this specimen: 27 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 14, Splice Site 3, 3'UTR 1, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 37/55 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BUD23 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as COSV99736893; called by muse, mutect2
- CCAR1 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV56268854; called by muse, mutect2, varscan2
- CHD4 | c.2950C>T p.L984F (on ENST00000357008 / NM_001363606.2; = p.L997F on NM_001273.5) | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779545095, COSV58898367; called by muse, mutect2, varscan2
- CLIC2 | c.293+1G>A p.X98_splice | Splice Site (SNP) | VAF 29/148 reads (20%) | catalogued as COSV58936152; called by muse, mutect2, varscan2
- CSAG1 | c.188G>T p.R63M | Missense Mutation (SNP) | VAF 70/389 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV63400109, COSV63400725; called by muse, mutect2, varscan2
- DDX25 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54989445; called by muse, mutect2, varscan2
- EIF2B5 | c.1571G>A p.G524E (on ENST00000647909; = p.G516E on NM_003907.3) | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV56604224; called by muse, mutect2, varscan2
- FAM241B | c.263C>A p.P88Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100958424, COSV64768184; called by muse, mutect2, varscan2
- FLG | c.9253G>C p.G3085R | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.171); catalogued as rs761303232, COSV64240018; called by muse, mutect2, varscan2
- IGSF1 | c.3730C>G p.L1244V | Missense Mutation (SNP) | VAF 118/334 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63836889; called by muse, mutect2, varscan2
- KCNT2 | c.819+2T>A p.X273_splice | Splice Site (SNP) | VAF 48/151 reads (32%) | catalogued as COSV54073356; called by muse, mutect2, varscan2
- MPP7 | c.888G>C p.R296S | Missense Mutation (SNP) | VAF 96/381 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV61731306; called by muse, mutect2, varscan2
- NUP214 | c.3310C>G p.Q1104E | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63908675; called by muse, mutect2
- OR5H6 | c.539T>C p.F180S (on ENST00000642105; = p.F164S on NM_001005479.2) | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV67351279; called by muse, mutect2, varscan2
- PKD2L1 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 91/240 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58395484; called by muse, mutect2, varscan2
- PLEKHB2 | c.581A>T p.Y194F (on ENST00000409279; = p.Y193F on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV52175352; called by muse, mutect2, varscan2
- PROM2 | c.498-1G>A p.X166_splice | Splice Site (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100469365; called by muse, mutect2, varscan2
- SNRNP200 | c.228G>C p.E76D | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV60488900; called by muse, mutect2, varscan2
- SYT12 | c.798G>T p.Q266H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV67353698; called by muse, mutect2, varscan2
- THOC2 | c.2883C>A p.D961E | Missense Mutation (SNP) | VAF 110/356 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.735); catalogued as COSV55543855; called by muse, mutect2, varscan2
- TTN | c.75093G>C p.K25031N (on ENST00000591111; = p.K17607N on NM_003319.4) | Missense Mutation (SNP) | VAF 129/378 reads (34%) | PolyPhen probably damaging (0.997); catalogued as rs762254728, COSV59981517; called by muse, mutect2, varscan2
- MOCOS | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- NUMA1 | c.2174_2188del p.A725_L729del | In Frame Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- RGS22 | c.403del p.S135Vfs*9 | Frame Shift Del (DEL) | VAF 34/129 reads (26%) | called by mutect2, pindel, varscan2
- TNFAIP3 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMYND8 | c.3116G>T p.C1039F (on ENST00000311275 / NM_001363741.2; = p.C1013F on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1E | c.3621C>T p.D1207= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV62389305; called by muse, mutect2, varscan2
- CCNI2 | c.477G>C p.R159= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs765981033, COSV101107879; called by muse, mutect2, varscan2
- IGF2R | c.3033C>G p.L1011= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV100808107; called by muse, mutect2
- MBTPS1 | c.1368C>G p.V456= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV58570195; called by muse, mutect2, varscan2
- MRRF | c.48C>T p.R16= | Silent (SNP) | VAF 61/176 reads (35%) | catalogued as COSV52913882; called by muse, mutect2, varscan2
- MUC17 | c.12300A>C p.T4100= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV60285340; called by muse, mutect2, varscan2
- SCN9A | c.3330G>A p.S1110= (on ENST00000303354; = p.S1099= on NM_002977.3) | Silent (SNP) | VAF 45/159 reads (28%) | catalogued as rs778381073, COSV57606009; called by muse, mutect2, varscan2
- SPG7 | c.1188C>T p.C396= (on ENST00000268704; = p.C403= on NM_003119.4) | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- SV2A | c.486C>T p.G162= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV64964530; called by muse, mutect2, varscan2
- TLR8 | c.1722A>T p.T574= (on ENST00000218032 / NM_138636.5; = p.T592= on NM_016610.4) | Silent (SNP) | VAF 74/150 reads (49%) | catalogued as COSV54317263; called by muse, mutect2, varscan2
- TOP2A | c.2304T>C p.I768= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV101396374; called by muse, mutect2
- XDH | c.3618C>T p.L1206= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV101052454; called by muse, mutect2, varscan2
- ZBP1 | c.213T>G p.T71= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV59061297, COSV59063172; called by muse, mutect2, varscan2
- ZC3H7B | c.904C>T p.L302= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100687733; called by muse, mutect2, varscan2
- SDC1 | c.*1C>T | 3'UTR (SNP) | VAF 4/17 reads (24%) | catalogued as rs376758793; called by mutect2, varscan2
